Surgical pathology report (de-identified scan), TCGA case TCGA-2H-A9GH, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Erasmus MC, specimen TCGA-2H-A9GH-01A (Primary Tumor).

Pathology Report

Coded sample ID:

Date of tumor procurement:

Date of report:

Histologic diagnosis: moderate differentiated adenocarcinoma in Barrett-epithelium

Anatomic site with laterality: distal esophagus

Tumor size: diameter 2 cm

Lymph node status: 11 lymph nodes, of which 1 contains tumor

Any comments or amendments: radical resection

ICD-0-3
Adenocarcinoma NOS 8140/3
Site: Esophagus, distal third
C15.5
JW 1/29/14

Source: NCI Genomic Data Commons file 9dae9e16-cc4a-4584-aac1-aed5a1dfefe2 (TCGA-2H-A9GH.47177922-F455-4CD4-BC07-B0559439BC86.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).